Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9JY, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9JY-01A (Primary Tumor).

ICD O-3
Carcinoma, papillary renal cell
8260/3
Site: (L) Kidney NOS
C64.9
7/5 6/13/14

Papillary Renal Cell Carcinoma, Type I

Stage: pT2, R0

Grade: GII

ICD-O-Code: 8260/3

Laterality = (L)

Source: NCI Genomic Data Commons file 13afc144-8d16-4c2e-9fb5-8418e088dda2 (TCGA-5P-A9JY.94A1D757-7DE9-4D9B-97AB-B6BD66C2CB3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).